Somatic mutation profile of tumor specimen TCGA-05-4418-01A (aliquot TCGA-05-4418-01A-01D-1265-08) from TCGA case TCGA-05-4418, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 69.6 years (25,417 days).
Specimen TCGA-05-4418-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2eae656-2df6-40df-bc06-478163e5bdab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4418-10A (Blood Derived Normal), aliquot TCGA-05-4418-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa1d3843-145a-4e36-9494-86eb54c0bcf8

The open-access MAF lists 301 somatic variants for this specimen: 228 protein-altering or splice-affecting, 63 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 63, Nonsense Mutation 11, Frame Shift Ins 5, RNA 5, Intron 4, Splice Region 3, Frame Shift Del 3, Splice Site 3, In Frame Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG5 | c.1067T>C p.F356S | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV53213155; called by muse, mutect2, varscan2
- AC013489.1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.099); catalogued as COSV51553204; called by muse, mutect2, varscan2
- AC109583.1 | c.299C>A p.P100Q | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.059); catalogued as COSV100167902; called by muse, mutect2, varscan2
- ACKR2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs868771798, COSV56177418; called by muse, mutect2, varscan2
- ACOXL | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs1363374003, COSV61329710; called by muse, mutect2, varscan2
- ACSL6 | c.1216A>G p.I406V (on ENST00000379240; = p.I431V on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV57304184; called by muse, mutect2, varscan2
- ADGRL2 | c.509T>C p.I170T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV54685146; called by muse, mutect2, varscan2
- AFF2 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 66/129 reads (51%) | catalogued as COSV54001443; called by muse, mutect2, varscan2
- AMD1 | c.773A>T p.N258I | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64388033; called by muse, mutect2, varscan2
- AMTN | c.284T>G p.L95R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59490004; called by muse, mutect2, varscan2
- ANK1 | c.2819C>A p.P940Q | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55893177; called by muse, mutect2, varscan2
- ANO6 | c.1552A>G p.I518V | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as COSV57667009; called by muse, mutect2
- ANXA3 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762302189, COSV53716592; called by muse, mutect2, varscan2
- APOB | c.9534G>C p.K3178N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV51949419; called by muse, mutect2, varscan2
- APOB | c.2604C>A p.N868K | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV51949437; called by muse, mutect2, varscan2
- APOB | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51949449; called by muse, mutect2, varscan2
- ARFIP2 | c.313A>T p.K105* | Nonsense Mutation (SNP) | VAF 24/114 reads (21%) | catalogued as COSV54448081; called by muse, mutect2, varscan2
- ARHGAP6 | c.2053C>A p.Q685K | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.131); catalogued as COSV57301879; called by muse, mutect2, varscan2
- ARHGEF11 | c.2841G>T p.R947S | Missense Mutation (SNP) | VAF 89/344 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV59357549; called by muse, mutect2, varscan2
- ARMH4 | c.2273G>A p.S758N | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1161096028, COSV50769170; called by muse, mutect2, varscan2
- AUH | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57865587; called by muse, mutect2, varscan2
- AXIN2 | c.1102G>C p.A368P | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.89); catalogued as COSV61057849, COSV61060193; called by muse, mutect2, varscan2
- BASP1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.686); catalogued as COSV59473041; called by muse, mutect2
- BCL11B | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV61738731; called by muse, mutect2, varscan2
- BTAF1 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV56438571; called by muse, mutect2, varscan2
- C1orf127 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as rs370186380; called by muse, mutect2, varscan2
- CBX3 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.273); catalogued as rs776140361, COSV100522906; called by muse, mutect2
- CDHR1 | c.552C>A p.D184E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV60565883; called by muse, mutect2, varscan2
- CENPF | c.5563G>T p.E1855* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV65278498; called by muse, mutect2, varscan2
- CEP131 | c.212A>G p.N71S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs1033358901, COSV53955907; called by muse, mutect2, varscan2
- CEP152 | c.4844G>T p.G1615V (on ENST00000380950 / NM_001194998.2; = p.G1559V on NM_014985.4) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV100359161; called by mutect2, varscan2
- CEP152 | c.4843G>T p.G1615C (on ENST00000380950 / NM_001194998.2; = p.G1559C on NM_014985.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs762169861, COSV57863588; called by mutect2, varscan2
- CHRND | c.1262C>A p.P421Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.877); catalogued as COSV51328815; called by muse, mutect2, varscan2
- CLCA2 | c.881C>A p.T294N | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV65288490; called by muse, mutect2, varscan2
- CLPB | c.1042A>G p.I348V | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.012); catalogued as COSV53632914; called by muse, mutect2, varscan2
- COL5A1 | c.3744+1G>C p.X1248_splice | Splice Site (SNP) | VAF 34/77 reads (44%) | catalogued as COSV100879643, COSV65673747; called by muse, mutect2, varscan2
- CPD | c.4127A>G p.Y1376C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56715682; called by muse, mutect2, varscan2
- CRACD | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV51729981; called by muse, mutect2, varscan2
- CRB1 | c.1574T>C p.F525S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.397); catalogued as COSV66332981; called by muse, mutect2, varscan2
- CSMD1 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs765683466, COSV68250166; called by muse, mutect2, varscan2
- CST9 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100980497; called by muse, mutect2, varscan2
- CTTNBP2 | c.2698G>T p.V900F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV50461994; called by muse, mutect2, varscan2
- DDX50 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | catalogued as COSV65293222; called by muse, mutect2, varscan2
- DIDO1 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV56622596, COSV56632585; called by muse, mutect2, varscan2
- DIO3 | c.663C>A p.S221R | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as COSV100832282; called by muse, mutect2, varscan2
- DIO3 | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100832288; called by muse, mutect2, varscan2
- DNAJC13 | c.4227C>A p.D1409E | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV53456702; called by muse, mutect2, varscan2
- DPF3 | c.226G>C p.A76P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63502692; called by muse, mutect2, varscan2
- DPP9 | c.1819C>T p.P607S (on ENST00000598800; = p.P636S on NM_139159.5) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs770820179, COSV53593913; called by muse, mutect2, varscan2
- DUOX2 | c.3498C>A p.N1166K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV66534209; called by muse, mutect2, varscan2
- EFCAB6 | c.3701A>C p.Y1234S | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV53070853; called by muse, mutect2, varscan2
- ERICH3 | c.3625C>A p.R1209S | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs762258316, COSV100444744, COSV58616267; called by muse, mutect2, varscan2
- FAM135B | c.2412G>C p.K804N | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV52728580, COSV52749022; called by muse, mutect2, varscan2
- FAM171A1 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV65314495, COSV65314800, COSV65319417; called by muse, mutect2, varscan2
- FASTKD2 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV52699964; called by muse, mutect2, varscan2
- FBXL7 | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61652068; called by muse, mutect2, varscan2
- FHL5 | c.428T>A p.I143N | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58740170; called by muse, mutect2
- FOXO3 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV59630819, COSV59631982; called by muse, mutect2, varscan2
- FREM2 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV54849611; called by muse, mutect2, varscan2
- FRMD6 | c.1118C>T p.A373V (on ENST00000344768 / NM_001267046.2; = p.A365V on NM_152330.4) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as rs371612348; called by muse, mutect2, varscan2
- GAL | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs541536020, COSV55763464, COSV55764567; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAS7 | c.1374G>C p.E458D (on ENST00000432992 / NM_201433.2; = p.E318D on NM_003644.3) | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60442619; called by muse, mutect2, varscan2
- GBA | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59170783; called by muse, mutect2, varscan2
- GCKR | c.1342C>A p.P448T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99269442; called by muse, mutect2, varscan2
- GCKR | c.1343C>A p.P448H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.646); catalogued as rs769677339, COSV99269444; called by muse, mutect2, varscan2
- GCN1 | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); catalogued as COSV56113744; called by muse, mutect2, varscan2
- GKN1 | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65006826; called by muse, mutect2, varscan2
- GLRA2 | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as COSV54346748; called by muse, mutect2, varscan2
- GPBP1 | c.332A>T p.H111L | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV53314023; called by muse, mutect2, varscan2
- GPRC6A | c.1536C>A p.F512L | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV59955482; called by muse, mutect2, varscan2
- GPT2 | c.1565A>G p.Y522C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60840019; called by muse, mutect2, varscan2
- GPX3 | c.367C>G p.R123G | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100161806; called by muse, mutect2, varscan2
- GRAMD4 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1051489823, COSV63029822; called by muse, mutect2, varscan2
- GRIN2B | c.4228A>C p.T1410P | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as COSV74207469; called by muse, mutect2, varscan2
- GRIP1 | c.2222A>C p.Q741P (on ENST00000359742 / NM_001379345.1; = p.Q689P on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV54039039; called by muse, mutect2, varscan2
- GRM2 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56587100; called by muse, mutect2, varscan2
- GRM7 | c.2125T>A p.L709I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV63165566; called by muse, mutect2, varscan2
- GUCA1C | c.423G>C p.K141N | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV53755901; called by muse, mutect2, varscan2
- HAUS3 | c.83_86del p.D28Gfs*12 | Frame Shift Del (DEL) | VAF 26/135 reads (19%) | catalogued as rs768714442; called by mutect2, pindel, varscan2
- HECTD4 | c.7271G>T p.G2424V | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66393207; called by muse, mutect2, varscan2
- HK3 | c.2625G>C p.P875= | Splice Region (SNP) | VAF 44/193 reads (23%) | catalogued as rs755376392, COSV52838173, COSV52843867; called by muse, mutect2, varscan2
- HOMEZ | c.199A>T p.N67Y | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100664197; called by muse, mutect2, varscan2
- IGF2BP2 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs758689947, COSV60490461; called by muse, mutect2
- IGSF8 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.484); catalogued as COSV58757651, COSV58759021; called by muse, mutect2, varscan2
- INHBA | c.520C>A p.R174S | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54221639, COSV54224543; called by muse, mutect2, varscan2
- INSM2 | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as rs770425438, COSV51875221; called by muse, mutect2, varscan2
- ITGA6 | c.1386G>A p.Q462= (on ENST00000442250; = p.Q423= on NM_000210.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 35/122 reads (29%) | catalogued as COSV51252071; called by muse, mutect2, varscan2
- ITGA8 | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV65234822; called by muse, mutect2, varscan2
- ITGAX | c.1583T>A p.L528Q | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51650569; called by muse, mutect2, varscan2
- IVL | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); catalogued as COSV64216925; called by muse, mutect2, varscan2
- KANK4 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1203830116, COSV62988898; called by muse, mutect2, varscan2
- KATNIP | c.3703G>T p.G1235C | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55177840, COSV55190181; called by muse, mutect2, varscan2
- KCNK10 | c.205T>C p.W69R | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as COSV56651231; called by muse, varscan2
- KCNQ2 | c.1951C>T p.P651S (on ENST00000359125 / NM_172107.4; = p.P623S on NM_004518.6) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.924); catalogued as COSV100609934, COSV60553082; called by muse, mutect2, varscan2
- KEAP1 | c.1378A>G p.R460G | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50637376; called by muse, mutect2, varscan2
- KIF18A | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54187028; called by muse, mutect2, varscan2
- KIF1B | c.3864G>A p.Q1288= (on ENST00000377086 / NM_001365952.1; = p.Q1242= on NM_015074.3) | Splice Region (SNP) | VAF 14/72 reads (19%) | catalogued as COSV55814985; called by muse, varscan2
- KIR3DL1 | c.407C>A p.S136* | Nonsense Mutation (SNP) | VAF 53/246 reads (22%) | catalogued as rs758317602; called by muse, mutect2, varscan2
- KLK7 | c.319C>A p.Q107K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100304502; called by muse, mutect2, varscan2
- KRTAP4-2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV100894566; called by muse, mutect2, varscan2
- LAMB2 | c.1949C>G p.A650G | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV100565508; called by muse, mutect2, varscan2
- LAMB2 | c.1948G>T p.A650S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV100565509; called by muse, mutect2, varscan2
- LDLRAP1 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100974820; called by muse, mutect2, varscan2
- LHX8 | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.982); catalogued as rs754988725, COSV53959562; called by muse, mutect2, varscan2
- LMBR1 | c.1045G>C p.A349P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.602); catalogued as COSV62222826; called by muse, mutect2, varscan2
- LRP1B | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1167413989, COSV67265504; called by muse, mutect2, varscan2
- LRRC8C | c.1364A>T p.K455M | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV65000543; called by muse, mutect2, varscan2
- MAGEB16 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV67874465; called by muse, mutect2, varscan2
- MAP3K12 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV57235597; called by muse, mutect2, varscan2
- MAPK9 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58125298; called by muse, mutect2, varscan2
- MARK4 | c.193A>T p.I65F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV53468057; called by muse, mutect2, varscan2
- MGA | c.5976G>T p.K1992N (on ENST00000219905 / NM_001164273.1; = p.K1783N on NM_001080541.2) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); catalogued as COSV54961532; called by muse, mutect2, varscan2
- MKNK1 | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57862707; called by muse, mutect2, varscan2
- MS4A2 | c.288T>G p.F96L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV54013638; called by muse, mutect2, varscan2
- MSH6 | c.2734T>C p.W912R | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1060502869, COSV52286303; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSLNL | c.1115A>C p.Q372P | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53505632; called by muse, mutect2, varscan2
- MTHFD2L | c.488C>T p.A163V (on ENST00000395759 / NM_001144978.2; = p.A105V on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV100306359; called by muse, mutect2
- MTREX | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV57929563; called by muse, mutect2, varscan2
- MUC16 | c.10283C>A p.S3428Y | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV101200032, COSV67488591; called by muse, mutect2, varscan2
- MYCBP2 | c.11031A>C p.E3677D (on ENST00000357337; = p.E3715D on NM_015057.5) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV62036035; called by muse, mutect2, varscan2
- MYH8 | c.1483C>A p.H495N | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV67971140; called by muse, mutect2, varscan2
- MYL10 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV56208882; called by muse, mutect2, varscan2
- MYO9A | c.6341A>G p.D2114G | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61856551; called by muse, mutect2, varscan2
- NAMPT | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55996406; called by muse, mutect2, varscan2
- NAP1L2 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.166); catalogued as rs1347469893, COSV65172988; called by muse, mutect2, varscan2
- NNT | c.2167A>G p.I723V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs1184437784, COSV52928858; called by muse, mutect2, varscan2
- NOS2 | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.749); catalogued as COSV58226924; called by muse, mutect2
- NRXN3 | c.1243A>T p.I415F (on ENST00000335750 / NM_001330195.2; = p.I42F on NM_004796.6) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.923); catalogued as COSV59798313; called by muse, mutect2, varscan2
- NUP133 | c.3065C>T p.A1022V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.102); catalogued as rs751402996, COSV54572931; called by muse, mutect2, varscan2
- OR1D5 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73859629, COSV73859693; called by muse, mutect2, varscan2
- OR1J1 | c.858C>A p.N286K | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs752032972, COSV52239619; called by muse, mutect2, varscan2
- OR2T12 | c.900A>T p.K300N | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV58779245; called by muse, mutect2
- OR4Q3 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59180021; called by muse, mutect2
- OR51D1 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62913961; called by muse, mutect2, varscan2
- OR5I1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100041704; called by muse, mutect2, varscan2
- OR8J3 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs775482925, COSV56882607; called by muse, mutect2, varscan2
- OR8U1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100164130; called by muse, mutect2
- OTOF | c.4054G>T p.D1352Y (on ENST00000272371 / NM_194248.3; = p.D585Y on NM_004802.4) | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV55505909; called by muse, mutect2, varscan2
- PCDHA12 | c.690A>G p.I230M | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56539247; called by muse, mutect2, varscan2
- PCDHA6 | c.219C>A p.D73E | Missense Mutation (SNP) | VAF 86/346 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs544173556, COSV65356942; called by muse, varscan2
- PCDHB4 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52021802, COSV52026244; called by muse, mutect2, varscan2
- PCDHGA9 | c.2150G>A p.R717K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as COSV54016603; called by muse, mutect2, varscan2
- PDIA4 | c.884A>T p.Q295L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV53726449; called by muse, mutect2, varscan2
- PHACTR3 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV63033295; called by muse, mutect2, varscan2
- PIP5K1C | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV58955382; called by muse, mutect2, varscan2
- PLK4 | c.2372G>A p.R791K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54639051; called by muse, mutect2, varscan2
- PPCS | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100999525; called by muse, mutect2, varscan2
- PPFIA1 | c.3187A>C p.I1063L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.292); catalogued as COSV54134918, COSV54139937; called by muse, mutect2, varscan2
- PPM1H | c.1433C>A p.A478D | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57378478; called by muse, mutect2, varscan2
- PRF1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV64615762; called by muse, mutect2, varscan2
- PRG4 | c.3158G>T p.R1053L | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs149799261, COSV63356358; called by muse, mutect2, varscan2
- PRKCA | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as rs563946455, COSV52591914, COSV52593848; called by muse, mutect2
- PRPF38B | c.809G>C p.R270P | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV64223703, COSV64224490; called by muse, mutect2, varscan2
- RANBP2 | c.9272G>T p.R3091L | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV51707209; called by muse, mutect2, varscan2
- RASGRF2 | c.1034A>G p.Y345C | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54138040; called by muse, mutect2, varscan2
- RBM10 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV61308478, COSV61311726; called by muse, mutect2, varscan2
- RBM15B | c.2529dup p.S844Vfs*121 | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | catalogued as rs781825075; called by mutect2, varscan2
- RIC3 | c.125-2A>T p.X42_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV58304388; called by muse, mutect2
- RIPK4 | c.1960A>G p.T654A (on ENST00000352483; = p.T606A on NM_020639.3) | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV60190502; called by muse, mutect2, varscan2
- RNF31 | c.1661C>G p.A554G | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV53761019; called by muse, mutect2, varscan2
- ROBO3 | c.1837A>G p.T613A | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as COSV67302560; called by muse, mutect2, varscan2
- SEMA3A | c.1568C>G p.A523G | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV54885333; called by muse, mutect2, varscan2
- SEMA6C | c.674A>T p.H225L | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV59007009; called by muse, mutect2, varscan2
- SEMA6D | c.2506G>T p.D836Y (on ENST00000316364 / NM_153618.2; = p.D774Y on NM_020858.2) | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV60382745; called by muse, mutect2, varscan2
- SETD1A | c.3992C>T p.P1331L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV52691767; called by muse, mutect2, varscan2
- SLC18A3 | c.196G>T p.G66W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100340896; called by muse, mutect2, varscan2
- SLC18A3 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs764453365, COSV100340897; called by muse, mutect2, varscan2
- SLC25A48 | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.331); catalogued as COSV50850842, COSV50850925; called by muse, mutect2, varscan2
- SLC29A4 | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV51876454; called by muse, mutect2, varscan2
- SLCO1A2 | c.547A>G p.I183V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.649); catalogued as COSV56609207; called by muse, mutect2, varscan2
- SLCO6A1 | c.1574T>A p.F525Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV65814054; called by muse, mutect2, varscan2
- SOCS6 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205871; called by muse, mutect2, varscan2
- SORCS1 | c.2928C>A p.F976L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs370004055; called by muse, mutect2, varscan2
- SOS2 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV99366804; called by muse, mutect2, varscan2
- SOX30 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV53939085; called by muse, mutect2, varscan2
- SPEF2 | c.2225C>T p.T742I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.426); catalogued as rs891929946, COSV61552766; called by muse, mutect2, varscan2
- SSUH2 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58032980; called by muse, mutect2, varscan2
- ST18 | c.1182C>A p.H394Q | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360755029, COSV52506685; called by muse, mutect2, varscan2
- STIP1 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59440669, COSV59441260; called by muse, mutect2, varscan2
- STK24 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64823592; called by muse, varscan2
- SUN5 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62182313; called by muse, mutect2, varscan2
- SV2C | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 30/112 reads (27%) | catalogued as rs748677235, COSV59218804, COSV59227560; called by muse, mutect2, varscan2
- SVOP | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 117/244 reads (48%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as COSV100139662; called by muse, mutect2, varscan2
- SYDE2 | c.2035T>C p.S679P | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52317728; called by muse, mutect2, varscan2
- TEX26 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); catalogued as COSV66840591; called by muse, mutect2, varscan2
- TGM4 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV56096059; called by muse, mutect2, varscan2
- THEMIS | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64070345, COSV64072144; called by muse, mutect2, varscan2
- TNRC6A | c.2990G>T p.R997L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59369243; called by muse, mutect2, varscan2
- TRPC3 | c.934C>A p.L312I (on ENST00000379645 / NM_001366479.2; = p.L239I on NM_003305.2) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53380135, COSV99313326; called by muse, mutect2, varscan2
- TTLL10 | c.998C>T p.A333V (on ENST00000379289 / NM_001130045.2; = p.A260V on NM_153254.3) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs866630539, COSV64961102; called by muse, mutect2
- UBA2 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV55830081; called by muse, mutect2, varscan2
- UBE4B | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV53540881; called by muse, mutect2, varscan2
- UBR3 | c.4389G>T p.L1463F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99774972; called by muse, mutect2, varscan2
- UBR4 | c.12133G>T p.V4045L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV100921886; called by muse, mutect2, varscan2
- UBR4 | c.10748G>T p.R3583L | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64397665; called by muse, mutect2, varscan2
- UGT3A1 | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV57102237; called by muse, mutect2, varscan2
- USP44 | c.117G>T p.W39C | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51566535; called by muse, mutect2, varscan2
- VIL1 | c.988G>T p.V330L | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV50295268; called by muse, mutect2, varscan2
- VN1R2 | c.912C>A p.Y304* | Nonsense Mutation (SNP) | VAF 55/204 reads (27%) | catalogued as COSV100448177; called by muse, mutect2, varscan2
- VPS53 | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs138068150, COSV52136317; called by muse, mutect2
- VPS53 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as rs1236211115, COSV52136343; called by muse, mutect2
- WRN | c.3124G>C p.A1042P | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as COSV53306100; called by muse, mutect2, varscan2
- YES1 | c.1534G>T p.D512Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV58852302; called by muse, mutect2, varscan2
- ZFHX3 | c.5962T>A p.C1988S | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51716965, COSV51732515; called by muse, mutect2, varscan2
- ZFYVE26 | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61332890; called by muse, mutect2, varscan2
- ZNF135 | c.1469G>T p.G490V (on ENST00000313434 / NM_001289401.2; = p.G502V on NM_003436.4) | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57885213; called by muse, mutect2
- ZNF221 | c.1165A>T p.T389S | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV52110929; called by muse, mutect2, varscan2
- ZNF248 | c.1479A>G p.I493M | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1244483810, COSV61998413; called by muse, mutect2, varscan2
- ZNF664 | c.247G>T p.V83L | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV61878632; called by muse, mutect2, varscan2
- ZNF676 | c.1345G>T p.G449* (on ENST00000650058; = p.G417* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV68093176, COSV68094669; called by muse, varscan2
- ZNF718 | c.900A>T p.E300D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.116); catalogued as COSV68140621; called by muse, mutect2, varscan2
- ZNHIT2 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as COSV99659422; called by muse, mutect2
- AC098582.1 | c.485dup p.N164Efs*55 | Frame Shift Ins (INS) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- ANXA8 | c.284A>C p.Y95S | Missense Mutation (SNP) | VAF 80/508 reads (16%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.812); called by muse, varscan2
- HDLBP | c.1145del p.K382Rfs*43 | Frame Shift Del (DEL) | VAF 103/426 reads (24%) | called by mutect2, pindel, varscan2
- ITGA3 | c.794dup p.N265Kfs*55 | Frame Shift Ins (INS) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- ITGBL1 | c.98+3_98+6del p.X33_splice | Splice Site (DEL) | VAF 21/90 reads (23%) | called by mutect2, pindel, varscan2
- MUC2 | c.1346T>A p.L449Q | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- NDUFAF7 | c.1085dup p.N362Kfs*5 | Frame Shift Ins (INS) | VAF 32/112 reads (29%) | called by mutect2, pindel, varscan2
- PIGG | c.1188_1190del p.K396_H397delinsN | In Frame Del (DEL) | VAF 34/157 reads (22%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.6C>A p.S2R | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SEC24B | c.3586dup p.M1196Nfs*23 | Frame Shift Ins (INS) | VAF 13/124 reads (10%) | called by mutect2, pindel, varscan2
- SIK2 | c.2535del p.Y846Ifs*32 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- TLN2 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- VPS16 | c.2311G>T p.E771* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | called by muse, varscan2
- VPS16 | c.2312A>T p.E771V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF33B | c.378_389del p.F126_V130delinsL | In Frame Del (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel
- ADAMTS5 | c.2742T>A p.P914= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV53184272; called by muse, mutect2, varscan2
- ADGRD1 | c.1875C>G p.L625= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV55455063; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1297C>T p.L433= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as rs752688426, COSV62007571; called by muse, mutect2
- ATP2B3 | c.2994C>T p.D998= | Silent (SNP) | VAF 51/93 reads (55%) | catalogued as rs782453695, COSV54853909; called by muse, mutect2, varscan2
- CACNA1S | c.1869G>T p.G623= | Silent (SNP) | VAF 91/328 reads (28%) | catalogued as COSV62943009; called by muse, mutect2, varscan2
- CDH6 | c.2187C>A p.A729= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV54076879; called by muse, mutect2, varscan2
- CHL1 | c.2067G>T p.V689= (on ENST00000397491 / NM_001253387.1; = p.V705= on NM_006614.4) | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV56604097; called by muse, mutect2, varscan2
- CRHR1 | c.612C>A p.T204= (on ENST00000398285 / NM_001145146.2; = p.T175= on NM_004382.5) | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV53284995; called by muse, mutect2, varscan2
- CSPG4 | c.4722G>C p.V1574= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV57900347; called by muse, mutect2, varscan2
- CSTF3 | c.1522C>A p.R508= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100124347, COSV60610150; called by muse, mutect2, varscan2
- FSTL5 | c.1755G>T p.T585= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV60190550, COSV60223461; called by muse, mutect2, varscan2
- GABRA1 | c.1131T>C p.P377= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV50111804; called by muse, mutect2, varscan2
- GABRA5 | c.834C>A p.S278= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV59485064; called by muse, mutect2, varscan2
- GNLY | c.399G>A p.E133= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV55703609; called by muse, mutect2, varscan2
- GPIHBP1 | c.471C>T p.P157= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs1282314892, COSV58209551, COSV58209576; called by muse, mutect2, varscan2
- GPR158 | c.2274T>C p.I758= | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as rs1184078183, COSV66280435; called by muse, mutect2, varscan2
- HEXD | c.678G>T p.T226= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100028038; called by muse, mutect2, varscan2
- HNRNPA0 | c.207C>T p.P69= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV100152955; called by muse, mutect2, varscan2
- HRNR | c.2565C>A p.G855= | Silent (SNP) | VAF 70/166 reads (42%) | catalogued as rs763111366, COSV64262081; called by muse, mutect2, varscan2
- IRF8 | c.375A>T p.A125= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV51900193; called by muse, mutect2, varscan2
- KCNK10 | c.1054C>A p.R352= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV56642228, COSV56651207; called by muse, mutect2
- LGR5 | c.2307C>T p.A769= | Silent (SNP) | VAF 100/231 reads (43%) | catalogued as COSV57009132, COSV99878202; called by muse, mutect2, varscan2
- LRRN2 | c.1594C>A p.R532= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV100912936, COSV65784549; called by muse, mutect2, varscan2
- MAN2C1 | c.1854G>A p.E618= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs764139426, COSV51239638; called by muse, mutect2, varscan2
- MAP3K12 | c.2074C>A p.R692= | Silent (SNP) | VAF 114/300 reads (38%) | catalogued as COSV57235622, COSV99913617; called by muse, mutect2, varscan2
- MAP3K5 | c.3660C>T p.T1220= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100753265; called by muse, mutect2, varscan2
- MME | c.1671C>A p.A557= | Silent (SNP) | VAF 34/165 reads (21%) | catalogued as rs199570214, COSV64710009; called by muse, mutect2, varscan2
- MYH13 | c.5235G>T p.V1745= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV52840431, COSV52842151; called by muse, mutect2, varscan2
- NOS2 | c.426A>G p.Q142= | Silent (SNP) | VAF 68/272 reads (25%) | catalogued as COSV58226916; called by muse, mutect2
- NRXN2 | c.3495G>T p.L1165= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV55461717; called by muse, mutect2, varscan2
- OLFML2B | c.777C>A p.I259= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV54199786; called by muse, mutect2, varscan2
- OR2L13 | c.858C>A p.P286= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV63555245; called by muse, mutect2, varscan2
- OR2M5 | c.471C>T p.I157= | Silent (SNP) | VAF 78/380 reads (21%) | catalogued as rs774591467, COSV100822885; called by muse, varscan2
- OR4N5 | c.660C>T p.V220= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV61321215; called by muse, mutect2, varscan2
- PCDH12 | c.2394G>A p.V798= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV51524029; called by muse, mutect2, varscan2
- PCDHB5 | c.2136G>A p.L712= | Silent (SNP) | VAF 46/238 reads (19%) | catalogued as rs782018086, COSV50666123; called by muse, mutect2, varscan2
- PCDHB7 | c.597G>T p.V199= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV50807669; called by muse, mutect2, varscan2
- PCDHGA4 | c.1569C>A p.A523= | Silent (SNP) | VAF 43/223 reads (19%) | catalogued as COSV54016585, COSV99544742; called by muse, mutect2, varscan2
- PGAP2 | c.246C>T p.G82= (on ENST00000463452 / NM_001346398.2; = p.G143= on NM_014489.4) | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as rs766547773, COSV99544602; called by muse, mutect2, varscan2
- PNLIPRP1 | c.504T>A p.I168= | Silent (SNP) | VAF 223/526 reads (42%) | catalogued as COSV62613211; called by muse, mutect2, varscan2
- PTPDC1 | c.1213C>T p.L405= (on ENST00000375360 / NM_177995.3; = p.L457= on NM_152422.4) | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV56626023; called by muse, mutect2, varscan2
- PXDN | c.1500C>T p.Y500= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs376728530; called by muse, mutect2
- RNF31 | c.1806A>T p.G602= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV53761021; called by muse, mutect2, varscan2
- SEC24D | c.180T>C p.G60= | Silent (SNP) | VAF 52/214 reads (24%) | catalogued as COSV54884084; called by muse, mutect2, varscan2
- SH3KBP1 | c.856T>C p.L286= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as rs1232349434, COSV65644222; called by muse, mutect2, varscan2
- SLC38A3 | c.1095G>T p.L365= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV68844008, COSV68844141; called by muse, mutect2, varscan2
- SLC6A9 | c.648C>G p.P216= (on ENST00000360584 / NM_201649.4; = p.P162= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as COSV62211943; called by muse, mutect2, varscan2
- SP7 | c.1053G>A p.E351= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as COSV58191906; called by muse, mutect2, varscan2
- SPAST | c.189G>T p.L63= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV59516941; called by muse, mutect2, varscan2
- SPTBN4 | c.7581G>A p.A2527= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs778898969, COSV52543063; called by muse, mutect2, varscan2
- TGFB1I1 | c.72C>A p.P24= (on ENST00000394863 / NM_001042454.3; = p.P7= on NM_015927.4) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV62357828; called by mutect2, varscan2
- TMEM132B | c.114C>T p.L38= | Silent (SNP) | VAF 35/243 reads (14%) | catalogued as COSV54766950; called by muse, mutect2, varscan2
- TMEM132D | c.2379C>A p.I793= | Silent (SNP) | VAF 88/225 reads (39%) | catalogued as COSV67158798, COSV67160296; called by muse, mutect2, varscan2
- TMEM74B | c.381C>T p.L127= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as rs371763334, COSV101121994; called by muse, mutect2, varscan2
- TREX2 | c.327G>T p.P109= (on ENST00000334497; = p.P66= on NM_080701.3) | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as rs781958630, COSV100444309; called by muse, mutect2, varscan2
- TRIM71 | c.726G>T p.P242= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV67472484; called by muse, mutect2, varscan2
- VPS13B | c.3255G>T p.L1085= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV62154639; called by muse, mutect2, varscan2
- ZNF135 | c.1467A>G p.T489= (on ENST00000313434 / NM_001289401.2; = p.T501= on NM_003436.4) | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs546609935, COSV57885193; called by muse, mutect2
- ZNF479 | c.456C>A p.T152= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100483072; called by muse, mutect2, varscan2
- ZNF536 | c.117C>A p.I39= | Silent (SNP) | VAF 41/180 reads (23%) | catalogued as COSV62832794, COSV62833508; called by muse, mutect2, varscan2
- ZNF761 | c.123T>C p.Y41= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as rs753085047, COSV61889352; called by muse, mutect2, varscan2
- ZNF813 | c.123T>C p.Y41= | Silent (SNP) | VAF 21/224 reads (9%) | called by muse, mutect2, varscan2
- ZP4 | c.1113C>A p.P371= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV63913140, COSV63913247; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845886 T>G | 5'Flank (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.589-35756C>T | Intron (SNP) | VAF 19/37 reads (51%) | catalogued as COSV61629833; called by muse, mutect2, varscan2
- ATP6AP1L | n.1521A>G | RNA (SNP) | VAF 74/259 reads (29%) | catalogued as COSV66475491; called by muse, mutect2, varscan2
- DCHS2 | n.793A>C | RNA (SNP) | VAF 46/185 reads (25%) | catalogued as COSV59737808; called by muse, mutect2, varscan2
- GCNT2 | c.925+26877A>G | Intron (SNP) | VAF 81/161 reads (50%) | catalogued as COSV100297420; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.535C>A | RNA (SNP) | VAF 48/225 reads (21%) | called by muse, mutect2, varscan2
- OR3A4P | n.364C>A | RNA (SNP) | VAF 23/127 reads (18%) | called by muse, mutect2, varscan2
- PDE4DIP | c.637-7203C>G | Intron (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100521766; called by muse, mutect2, varscan2
- SND1 | c.1779+6956G>C | Intron (SNP) | VAF 34/158 reads (22%) | catalogued as COSV100691102; called by muse, mutect2, varscan2
- SSPOP | n.14381G>T | RNA (SNP) | VAF 27/166 reads (16%) | catalogued as COSV65135824; called by muse, mutect2, varscan2
